Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4636, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4636-01A (Primary Tumor).

Pathology Report
DIAGNOSIS

TCGA - CJ - 4636

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (7.0 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE (60% CLEAR CELLS, 40% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 3, INVASIVE INTO RENAL SINUS ADIPOSE TISSUE AND RENAL PELVICALYCEAL SYSTEM. (SEE COMMENT)

Margins of resection free of tumor.

Adrenal gland, no tumor present.

(B) PARACAVAL, INTERAORTIC CAVAL LYMPH NODES:

Four lymph nodes, no tumor present.

COMMENT

Renal cell carcinoma in the right kidney invades into the renal sinus adipose tissue and the renal pelvicalyceal system. There is no invasion into the perinephric adipose tissue or the renal vein. Multifocal necrosis is present. The kidney parenchyma shows hemorrhage in the renal tubules.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A radical nephrectomy specimen (21.0 x 12.0 x 7.0 cm), including the right kidney (12.5 x 9.0 x 6.5 cm), a segment of renal artery, the renal vein, ureter (5.0 cm in length and 0.5 cm in average diameter) and the adrenal gland (6.5 x 3.0 x 0.9 cm). There is a 7.0 x 5.5 x 5.0 cm well circumscribed tumor in the mid pole of the kidney. The tumor is golden yellow, with extensive areas of hemorrhage and necrosis, which are present predominantly in the center of the tumor. The tumor extends into the renal sinus and renal pelvis. The tumor does not invade into the perinephric adipose tissue or renal vein.

The adjacent kidney parenchyma has multifocal black striated foci of discoloration in the renal cortex. Otherwise, the kidney parenchyma is unremarkable. The pelvicalyceal system is smooth and devoid of other lesions. No lymph nodes are identified in the hilum or the kidney.

Serial cross sections of the right adrenal gland show unremarkable cortex and medulla.

Portions of the tumor have been submitted for possible electron microscopy as well as for vaccine protocol.

SECTION CODE: A1, ureter and vascular margins, A2-A4, tumor with renal sinus and pelvis; A5, tumor in renal pelvis; A6, tumor and renal pelvis; A7, A8, tumor and perinephric fat; A9, tumor and adjacent kidney; A10, A11, uninvolved renal parenchyma; A12, adrenal gland, representative section.

(B) PARACAVAL INTER AORTIC LYMPH NODE - A segment of adipose tissue (6.2 x 4.5 x 1.0 cm) with four possible unremarkable lymph nodes (from 0.8 to 4.0 cm in greatest dimension).

SECTION CODE: B1-B4, one possible lymph node; B5-B8, one possible lymph node; B9, two possible lymph nodes.

CLINICAL HISTORY

Renal mass.

Source: NCI Genomic Data Commons file 12efd2a7-7ae2-4c5b-ab41-a867a02ad6a7 (TCGA-CJ-4636.2327C1D8-E7CB-49EA-8387-C852EB23624C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).